Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84O, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84O-01A (Primary Tumor).

[page 1 of 2]
DOB :
Location :

Sex F

Specimen : Tissue

Episode No :

Collection : at

Lab No :

CLINICAL:
R insular tumour, ? glioma.

ICD-O-3
Oligodendroglioma, grade III
Site Brain, supratentorial NOS
path
R Brain, insular
945113
C71.0
94103013

MACROSCOPIC:
Specimen labelled "Brain tumour", consists of multiple pieces of light grey tissue which range in size between 1-15mm in maximum dimension with an aggregate measurement of 22 x 20 x 8mm. AE 1 block.

MICROSCOPIC: (Reported by

The sections show an infiltrative tumour with adjacent non-neoplastic brain. The tumour is hypercellular and is composed of a diffuse infiltrate of cells with predominantly round to slightly irregular nuclei with a surrounding pale zone of perinuclear clearing. Occasional mini gemistocytic cells are seen. The tumour contains a delicate ramifying vasculature. Larger calibre blood vessels are also present within the tumour, however, endothelial proliferation is not identified. Mitoses are frequent and are easily identified. There is a small focus of likely necrosis. The tumour cells are negative for GFAP. The Ki67 proliferative index is focally up to approximately 10%.

COMMENT:

The right insular tumour is an oligodendroglioma. The grading of oligodendrogliomas is difficult as definite criteria for the designation of anaplastic oligodendroglioma (Grade 3, WHO 2007) are not precisely established. Nonetheless, the presence of readily identifiable mitoses in this case, accompanied by a microscopic focus of necrosis and an elevated Ki67 proliferative index are worrying for progression to an anaplastic oligodendroglioma despite absence of microvascular proliferation. Testing for loss of heterozygosity at 1p/19q is also suggested.

Distribution : FILE-COPY,

[page 2 of 2]
DIAGNOSIS:

Right insular tumour: Oligodendroglioma with some features of anaplasia (Grade 2 to 3, WHO 2007) (see comment).

REPORTED BY :
AUTHORISED BY

DISEASE Codes :T-A0100,M-94503

Page 2 of 2

Primary Tumour Site Discrepancy		

W 9/22/13

QUAI/ELP

Source: NCI Genomic Data Commons file e6f30838-19c7-46f3-9b56-8b3fd392aeb4 (TCGA-TM-A84O.6E28D951-BB27-4E32-A681-46D1DEF900BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).